Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8078, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8078-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

		OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path
Report

STOMACH TISSUE
CHECKLIST

Specimen type: Subtotal
gastrectomy
Tumor site: Fundus
Tumor size: 14 x 13 x 2 cm
Tumor features: Ulcerated
Histologic type:
Adenocarcinoma
Histologic grade: Poorly
differentiated
Tumor extent: Adjacent
structures (specify) -
Omentum
Lymph nodes: 0/5 positive
for metastasis (Regional
0/5)
Lymphatic invasion: Not
specified
Venous invasion: Not
specified
Perineural invasion: Not
specified
Margins: Uninvolved
Evidence of neo-adjuvant
treatment: Not specified
Additional pathologic
findings: Not specified
Comments: None

Laterality

Fundus

Excision date

Source: NCI Genomic Data Commons file 9f81cbe0-ad06-42ec-8ade-0221627547a3 (TCGA-BR-8078.999A1B85-577D-4BCA-BCC3-26CF849A01EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).